CGCI case BLGSP-71-06-00015 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/192a6cab-1aeb-4685-8c09-b25dd2743d02

Demographics
Sex at birth: female; Race: black or african american; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: primary; Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 719 days (2.0 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Maxilla; Sites of involvement: Maxilla.
   Pathology details: Lymph node involved site: Submandibular; Tumor largest dimension diameter: 10 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COM; Days to treatment start: 2 days; Days to treatment end: 83 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 2 days; Days to treatment end: 83 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 359 days; Disease response: Tumor Free.
- Days to follow up: 719 days (2.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 445 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Weight: 21 kg; Height: 126 cm; BMI: 13.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen; Days to sample procurement: 0 days; Initial weight: 290 mg; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00015-01A-01-S2-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-06-00015-01A-02-S1-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00015-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00015-01B-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-06-00015-01B-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00015-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00015-01-HE: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD3: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD3-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD20-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-BCL6-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-BCL6-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-Ki67-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD10: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-BCL6: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-BCL2-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD10-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-HE-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD20-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD20: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-Ki67: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-HE-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD10-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-Ki67-1: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-BCL2-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-CD3-1-20X: Tissue microarray coordinates: D1,B2,F4.
  Slide BLGSP-71-06-00015-01-BCL2: Tissue microarray coordinates: D1,B2,F4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 445; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
